CGCI case HTMCP-02-15-01099 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Epithelial Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/22e4e0e3-84c4-4600-8f45-6c569087797d

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Adenosquamous carcinoma: ICD-O-3 morphology code: 8560/3; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 59.6 years (21,753 days); Year of diagnosis: 2014; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N1; AJCC clinical M: MX; AJCC clinical stage: Stage II; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 256 days.
   Pathology details: Lymph nodes positive: 1; Lymph nodes tested: 3.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 70 days; Disease response: Tumor Free.
- Follow-up contacts recording only the day: day -839, day 256.

Molecular and laboratory tests
- Test (IHC): Positive; Specialized molecular test: P40.

Other clinical attributes
- Day -839: Risk factors: HIV/AIDS.
- Day -839: Comorbidities: HIV/AIDS.
- Day 0: Risk factors: Hepatitis C Infection.
- Day 0: Weight: 79.83 kg; Height: 172.2 cm; BMI: 26.9; CD4 count: 844; Haart treatment indicator: Yes; HIV viral load: 40.
- Day 0: Comorbidities: Hepatitis C Infection.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.
- Day 70: Nadir CD4 count: 694.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 8.85.

Biospecimens (3 samples)
- Sample HTMCP-02-15-01099-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-15-01099-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-15-01099-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Adenosquamous; Tumor status: Tumor free; Height cm at diagnosis: 172.2 cm; Tobacco smoking age started: 17; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; Tobacco smoking history indicator: 2; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- History of disease: Year of HIV diagnosis: 2012; Hbv test results: Negative; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; History relevant infectious diagnosis: Syphilis and Hepatitis C.
- Primary pathology: Lymph nodes examined: Yes; Other pos node location: Peribronchial Ipsilateral.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-15-01099-01A-01E-11869:
- % tumour top: 75
- % tumour bottom: 75

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-15-01099-01A-01S-11869:
- % tumour top: 75
- % tumour bottom: 75
